Somatic mutation profile of tumor specimen TCGA-BR-8059-01A (aliquot TCGA-BR-8059-01A-11D-2340-08) from TCGA case TCGA-BR-8059, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 72.5 years (26,474 days).
Specimen TCGA-BR-8059-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 149722c1-9bd7-4295-95c8-45f0243680f1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-8059-10A (Blood Derived Normal), aliquot TCGA-BR-8059-10A-01D-2340-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4ee0ad5-2baa-46e0-8683-635315d6b3e4

The open-access MAF lists 806 somatic variants for this specimen: 640 protein-altering or splice-affecting, 154 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 466, Silent 154, Frame Shift Del 99, Nonsense Mutation 32, Frame Shift Ins 18, Splice Site 12, In Frame Del 7, Intron 5, Splice Region 3, RNA 3, In Frame Ins 2, 5'UTR 1.

Variants (750 of 806; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC8 | c.2506C>T p.R836* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as rs72559722, CM001605, COSV56849386; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- CASK | c.2270dup p.N757Kfs*38 (on ENST00000378163 / NM_001367721.1; = p.N752Kfs*38 on NM_003688.3) | Frame Shift Ins (INS) | VAF 8/38 reads (21%) | catalogued as rs886041645; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 7/55 reads (13%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KANSL1 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 7/124 reads (6%) | catalogued as rs149830411; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- KIT | c.1926A>C p.K642N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519907, COSV55397309; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/30 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- TMEM200C | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV67309264, COSV67309384; called by muse, mutect2, varscan2
- VPS13B | c.9850dup p.I3284Nfs*10 | Frame Shift Ins (INS) | VAF 12/69 reads (17%) | catalogued as rs774357106; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- A2M | c.3643G>A p.A1215T | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.489); catalogued as rs1294347145, COSV59385517; called by muse, mutect2, varscan2
- ABCA12 | c.1061+1G>C p.X354_splice (on ENST00000272895 / NM_173076.3; = p.X36_splice on NM_015657.3) | Splice Site (SNP) | VAF 14/86 reads (16%) | catalogued as COSV55956443; called by muse, mutect2, varscan2
- ABCB11 | c.1853C>T p.S618F | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV55589107; called by muse, mutect2
- ABCC6 | c.826G>A p.G276S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs200051606, COSV52743291, COSV99229092; called by muse, mutect2, varscan2
- ABHD16A | c.1553A>C p.D518A | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.376); catalogued as COSV65451662; called by muse, mutect2, varscan2
- ABITRAM | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100336541; called by muse, mutect2, varscan2
- AC011455.2 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs779303412, COSV55499288; called by muse, mutect2, varscan2
- ACAD10 | c.1781G>A p.W594* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as COSV58155870; called by muse, mutect2, varscan2
- ADAM17 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs548923032, COSV60398438, COSV60398995; called by muse, mutect2, varscan2
- ADAM2 | c.1755A>T p.Q585H | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV55861210; called by muse, mutect2, varscan2
- ADAM30 | c.844del p.S282Vfs*3 | Frame Shift Del (DEL) | VAF 9/56 reads (16%) | catalogued as rs757984494, COSV65561192; called by mutect2, pindel, varscan2
- ADAMTS18 | c.941T>A p.V314D | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51405512; called by muse, mutect2, varscan2
- ADAMTSL2 | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1478392567, COSV63203838; called by muse, mutect2
- ADCY8 | c.691G>A p.V231M | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.12); catalogued as COSV53904773; called by muse, mutect2, varscan2
- ADCY9 | c.1735T>A p.S579T | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV53574359; called by muse, mutect2, varscan2
- ADGRB3 | c.1243A>C p.T415P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV65391863; called by muse, mutect2, varscan2
- ADGRG1 | c.342C>A p.D114E | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV101113413; called by muse, mutect2, varscan2
- ADPRS | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768003962, COSV52880793; called by muse, mutect2, varscan2
- AGO4 | c.1912C>T p.Q638* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV64616993; called by muse, mutect2, varscan2
- AGTPBP1 | c.3110G>A p.W1037* (on ENST00000357081 / NM_001330701.2; = p.W997* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 25/143 reads (17%) | catalogued as COSV61270825; called by muse, varscan2
- AKAP9 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as COSV62344116; called by muse, mutect2, varscan2
- AMPH | c.2050G>T p.G684C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57739429, COSV57740048, COSV57759654; called by muse, mutect2, varscan2
- AMPH | c.1041A>T p.K347N | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); catalogued as COSV57740066; called by muse, mutect2, varscan2
- ANKAR | c.3509T>C p.I1170T | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55611817; called by muse, mutect2, varscan2
- ANKRD53 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs371861657; called by muse, mutect2, varscan2
- ANKRD55 | c.1429C>T p.Q477* | Nonsense Mutation (SNP) | VAF 26/163 reads (16%) | catalogued as COSV100591311; called by muse, mutect2, varscan2
- ANKS1B | c.910C>A p.Q304K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs758201572, COSV61347472; called by muse, mutect2, varscan2
- ANO4 | c.2513G>T p.R838L (on ENST00000392977 / NM_001286615.2; = p.R803L on NM_178826.4) | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.376); catalogued as COSV54596564, COSV54598541; called by muse, mutect2
- ANP32E | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV58481902; called by muse, mutect2, varscan2
- APBB1IP | c.100C>G p.P34A | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV63302622; called by muse, mutect2
- APH1A | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.826); catalogued as rs782767356, COSV52528838; called by muse, mutect2, varscan2
- APPL2 | c.633del p.F211Lfs*28 | Frame Shift Del (DEL) | VAF 17/106 reads (16%) | catalogued as COSV51591248; called by mutect2, pindel, varscan2
- ARHGAP33 | c.957G>T p.E319D | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as COSV50122058; called by muse, mutect2
- ARHGAP5 | c.3490G>A p.A1164T | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.005); catalogued as COSV61535143; called by muse, mutect2, varscan2
- ARID1A | c.3793G>A p.G1265S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.98); PolyPhen benign (0.015); catalogued as rs953652494, COSV61376024; called by muse, mutect2, varscan2
- ARMC4 | c.2506C>T p.R836C | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs369264618; ClinVar: uncertain significance; called by muse, mutect2
- ASIC5 | c.412G>T p.V138F | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.166); catalogued as COSV72232661; called by muse, mutect2, varscan2
- ATF6 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV63407169; called by muse, mutect2, varscan2
- ATP13A1 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs144897534; called by mutect2, varscan2
- ATP1A3 | c.1071G>T p.K357N (on ENST00000545399 / NM_001256214.2; = p.K344N on NM_152296.5) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV57486984; called by muse, mutect2, varscan2
- ATR | c.3475A>T p.M1159L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.135); catalogued as rs1276028936, COSV63385905; called by muse, mutect2, varscan2
- ATXN7L2 | c.223C>G p.H75D | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.419); catalogued as COSV63992231; called by muse, mutect2, varscan2
- BAG5 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV54570852; called by muse, mutect2, varscan2
- BARD1 | c.2258G>A p.G753D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867281641, COSV53611270; called by muse, mutect2, varscan2
- BCAS3 | c.2674A>G p.N892D (on ENST00000390652 / NM_001353144.2; = p.N877D on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV101175919; called by muse, mutect2
- BNC1 | c.1124A>C p.H375P | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61757189; called by muse, mutect2, varscan2
- BPTF | c.6256A>T p.T2086S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV58835933; called by muse, mutect2, varscan2
- BRAF | c.2405C>T p.A802V (on ENST00000288602 / NM_001374244.1; = p.A762V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 43/416 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs775889922, COSV56115442, COSV56368837; called by muse, mutect2
- C12orf50 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53894830; called by muse, mutect2, varscan2
- C16orf78 | c.694T>G p.L232V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs755381344, COSV54556089; called by muse, mutect2, varscan2
- C1QTNF6 | c.305C>G p.P102R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55396268; called by muse, mutect2
- C1orf116 | c.192G>T p.E64D | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63943992; called by muse, mutect2, varscan2
- CA13 | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 27/154 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV58797655; called by muse, mutect2, varscan2
- CALCR | c.1350G>T p.E450D (on ENST00000649521 / NM_001164737.2; = p.E434D on NM_001742.4) | Missense Mutation (SNP) | VAF 22/131 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.225); catalogued as COSV64007554; called by muse, mutect2, varscan2
- CARMIL3 | c.2428A>G p.I810V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.847); catalogued as COSV57726049; called by muse, mutect2, varscan2
- CASKIN1 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1192919208, COSV58871919; called by muse, mutect2, varscan2
- CASKIN1 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58871932; called by muse, mutect2, varscan2
- CASS4 | c.1153T>C p.S385P | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV64386119; called by muse, mutect2, varscan2
- CATIP | c.368T>C p.F123S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV56822539; called by muse, mutect2, varscan2
- CATSPER1 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100375954; called by muse, mutect2
- CATSPERG | c.3404G>A p.G1135D | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.08); catalogued as COSV53048101; called by muse, mutect2, varscan2
- CBX5 | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as rs778228591, COSV52936525; called by muse, mutect2, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 12/116 reads (10%) | catalogued as rs756536005; called by mutect2, pindel, varscan2
- CCDC116 | c.252C>A p.D84E | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.1); catalogued as rs752871423, COSV53037508; called by muse, mutect2, varscan2
- CCDC149 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1268753550, COSV60878484; called by muse, mutect2
- CCDC18 | c.1827+1G>T p.X609_splice (on ENST00000343253 / NM_001306076.1; = p.X610_splice on NM_206886.4) | Splice Site (SNP) | VAF 10/56 reads (18%) | catalogued as COSV58142916; called by muse, mutect2, varscan2
- CCDC40 | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as rs760027732, COSV66474260; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCNL2 | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs751164412, COSV68766331; called by muse, mutect2, varscan2
- CD1A | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56861463; called by muse, mutect2, varscan2
- CD300LB | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV58725598; called by muse, mutect2, varscan2
- CD99L2 | c.656A>T p.Q219L | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV60935813; called by muse, mutect2
- CDADC1 | c.1054A>C p.S352R | Missense Mutation (SNP) | VAF 52/280 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.1); catalogued as rs1271343653, COSV51911217; called by muse, mutect2, varscan2
- CDC42BPG | c.3889G>A p.A1297T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as rs1445705603, COSV61345688; called by mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as rs762194001; called by mutect2, varscan2
- CDH11 | c.1621T>C p.F541L | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV51759300; called by muse, mutect2
- CDH13 | c.378A>T p.K126N | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.104); catalogued as rs1389180769, COSV51812267; called by muse, mutect2, varscan2
- CDHR3 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.145); catalogued as COSV58416049; called by muse, mutect2, varscan2
- CDKL5 | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); catalogued as COSV66110968; called by muse, mutect2, varscan2
- CELSR1 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53084766; called by muse, mutect2, varscan2
- CELSR2 | c.3601C>T p.P1201S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.075); catalogued as COSV54770193; called by muse, mutect2
- CELSR3 | c.5038C>T p.P1680S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV50850146; called by muse, mutect2, varscan2
- CELSR3 | c.3136C>A p.P1046T | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.752); catalogued as COSV50850222; called by muse, mutect2, varscan2
- CEMIP | c.1687G>A p.G563S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs147046826; called by muse, mutect2, varscan2
- CENPF | c.6011T>C p.V2004A | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0.073); catalogued as COSV65273351; called by muse, mutect2
- CEP131 | c.930G>T p.E310D | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV53952452; called by muse, mutect2, varscan2
- CFAP126 | c.227del p.P76Lfs*4 | Frame Shift Del (DEL) | VAF 18/159 reads (11%) | catalogued as rs780823798; called by mutect2, varscan2
- CFAP74 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.58); PolyPhen benign (0.388); catalogued as rs868704620, COSV54566115; called by muse, mutect2, varscan2
- CHD7 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.982); catalogued as rs768014298, COSV101418164, COSV71109451; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST2 | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as COSV58885279; called by muse, mutect2
- CHSY3 | c.2135C>T p.T712I | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as COSV59276330; called by muse, mutect2, varscan2
- CIB4 | c.47A>T p.E16V | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV56600337; called by muse, mutect2, varscan2
- CLCF1 | c.146A>G p.Y49C | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as COSV56861570; called by muse, mutect2, varscan2
- CLIP4 | c.1185del p.D396Ifs*19 | Frame Shift Del (DEL) | VAF 9/48 reads (19%) | catalogued as rs1332364476; called by mutect2, pindel, varscan2
- CLOCK | c.53A>C p.D18A | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV59401478; called by muse, mutect2, varscan2
- CLPTM1 | c.223C>T p.R75* | Nonsense Mutation (SNP) | VAF 11/64 reads (17%) | catalogued as rs772409757, COSV61611699; called by muse, mutect2, varscan2
- CMSS1 | c.691A>G p.K231E | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV70436933, COSV70437677; called by muse, mutect2, varscan2
- CNGA2 | c.1835A>G p.Y612C | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV61704060; called by muse, mutect2, varscan2
- CNTN3 | c.2134G>A p.G712R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs777506457, COSV55166710; called by muse, mutect2
- COBLL1 | c.3500C>T p.S1167L (on ENST00000392717; = p.S1129L on NM_014900.5) | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs557248063, COSV52066729; called by muse, mutect2, varscan2
- COG5 | c.1410del p.P472Rfs*19 | Frame Shift Del (DEL) | VAF 16/105 reads (15%) | catalogued as COSV51764686; called by mutect2, pindel, varscan2
- COL6A3 | c.3837C>G p.D1279E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.49); catalogued as COSV55087116; called by muse, mutect2, varscan2
- COLEC12 | c.1968del p.K656Nfs*4 | Frame Shift Del (DEL) | VAF 7/41 reads (17%) | catalogued as COSV101232229; called by mutect2, pindel, varscan2
- CPQ | c.1381G>A p.V461I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as COSV55143869; called by muse, mutect2
- CRB1 | c.3064A>C p.S1022R | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV66328752; called by muse, mutect2, varscan2
- CRYBB3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs537796250, COSV53194428; called by muse, mutect2, varscan2
- CSAD | c.593C>T p.A198V (on ENST00000444623 / NM_001244705.2; = p.A225V on NM_015989.5) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV57242294; called by muse, mutect2, varscan2
- CSGALNACT1 | c.551T>G p.I184S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV59976655; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 6/25 reads (24%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CUL7 | c.2974C>T p.R992W | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); catalogued as rs1301329334, COSV54815794; called by muse, mutect2
- CUX2 | c.1159-1G>T p.X387_splice | Splice Site (SNP) | VAF 5/39 reads (13%) | catalogued as COSV99919680; called by muse, mutect2, varscan2
- CYP27B1 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs777588673, COSV56984268; called by muse, mutect2, varscan2
- CYP4A22 | c.412A>C p.T138P | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV53739423, COSV53739677; called by muse, mutect2, varscan2
- CYP4B1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs752316206, COSV54721991; called by muse, mutect2, varscan2
- CYP7B1 | c.390A>C p.K130N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV59586829; called by muse, mutect2, varscan2
- DCAF7 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV60407070; called by muse, mutect2
- DDR1 | c.2176G>C p.A726P (on ENST00000324771; = p.A689P on NM_001954.4) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as COSV61320809, COSV61322916, COSV61323522; called by muse, mutect2
- DGCR2 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs142513620; called by muse, mutect2, varscan2
- DIAPH1 | c.3301T>C p.Y1101H | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.376); catalogued as COSV53881250; called by muse, mutect2, varscan2
- DIAPH1 | c.2901A>C p.L967F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1293342147, COSV53881263; called by muse, mutect2, varscan2
- DIRAS3 | c.643A>G p.M215V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV63970662; called by muse, mutect2, varscan2
- DNAH11 | c.1320del p.K440Nfs*11 | Frame Shift Del (DEL) | VAF 9/87 reads (10%) | catalogued as rs1562668233; called by mutect2, pindel, varscan2
- DNAH5 | c.10888C>G p.H3630D | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.163); catalogued as COSV54219534, COSV54229318; called by mutect2, varscan2
- DNAH5 | c.5195C>T p.A1732V | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1018336173, COSV99449815; called by muse, mutect2, varscan2
- DNAH5 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.037); catalogued as rs1158371559, COSV54219545; called by muse, mutect2
- DNAH9 | c.11815G>T p.E3939* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV52350024, COSV99305877; called by muse, mutect2, varscan2
- DNAJC8 | c.245T>C p.I82T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.902); catalogued as COSV55281383; called by muse, mutect2, varscan2
- DNMBP | c.2939G>A p.G980D | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.911); catalogued as COSV60624050; called by muse, mutect2, varscan2
- DNMT1 | c.3701G>A p.R1234H | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61578649; called by muse, mutect2, varscan2
- DOCK2 | c.3512T>G p.V1171G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.368); catalogued as COSV56954518; called by muse, mutect2, varscan2
- DOCK2 | c.5057C>T p.P1686L | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs377714619; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | catalogued as rs782552436; called by pindel, varscan2
- DOCK6 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs575157102, COSV53913686; called by muse, mutect2, varscan2
- DPAGT1 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as rs867960487, COSV53828226; called by muse, mutect2, varscan2
- DQX1 | c.1622C>G p.A541G | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1283359673, COSV52045684; called by muse, mutect2, varscan2
- DSEL | c.1874A>G p.K625R | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59490499, COSV59490917; called by muse, mutect2, varscan2
- DSG3 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1465435498, COSV57125716; called by muse, mutect2, varscan2
- DST | c.10322G>C p.G3441A | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.73); catalogued as COSV54998732, COSV99756004; called by muse, mutect2, varscan2
- DUOX2 | c.2972del p.G991Efs*5 | Frame Shift Del (DEL) | VAF 17/97 reads (18%) | catalogued as COSV66533330; called by mutect2, pindel, varscan2
- ECSIT | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as rs761854037, COSV52939170; called by muse, mutect2, varscan2
- EEF1A1 | c.806C>G p.T269S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.211); catalogued as COSV58549402; called by muse, mutect2, varscan2
- ELMO1 | c.659C>T p.A220V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs776057144, COSV100164366, COSV60302254, COSV99068342; called by muse, mutect2, varscan2
- EPHA10 | c.2134G>A p.V712I | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs753810317, COSV57626608; called by mutect2, varscan2
- EPHB3 | c.1453G>T p.D485Y | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57805475; called by muse, mutect2, varscan2
- EPHB4 | c.901G>A p.V301I | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs749289689, COSV62268637; called by muse, mutect2, varscan2
- ERAP1 | c.1424dup p.N475Kfs*7 | Frame Shift Ins (INS) | VAF 23/163 reads (14%) | catalogued as rs750625401; called by mutect2, pindel, varscan2
- ERBB3 | c.3710G>A p.S1237N | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.614); catalogued as COSV57251355; called by muse, mutect2
- ERICH5 | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as COSV59315623; called by muse, mutect2, varscan2
- ERMP1 | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as rs774581636, COSV53037168; called by muse, mutect2, varscan2
- EZR | c.655G>C p.G219R | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61453474; called by muse, mutect2
- F5 | c.5014G>A p.A1672T | Missense Mutation (SNP) | VAF 8/107 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1294790083, COSV63123111; called by muse, mutect2
- FAM13C | c.537G>T p.K179N | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV53247221; called by muse, mutect2, varscan2
- FAM193A | c.2371T>A p.C791S | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61193247; called by muse, mutect2, varscan2
- FAM214A | c.2042del p.N681Mfs*5 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs762546731, COSV55927849; called by mutect2, varscan2
- FAM78B | c.782A>C p.K261T | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV57976661, COSV57979347; called by muse, mutect2, varscan2
- FAM83B | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs372267421; called by muse, varscan2
- FAM83F | c.1325T>A p.L442H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.436); catalogued as COSV60999992; called by muse, mutect2
- FAM8A1 | c.1173dup p.Q392Sfs*3 | Frame Shift Ins (INS) | VAF 72/154 reads (47%) | catalogued as rs1207864692; called by mutect2, varscan2
- FANCM | c.1487T>G p.L496R | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57500159; called by muse, mutect2, varscan2
- FAT3 | c.7216T>G p.L2406V | Missense Mutation (SNP) | VAF 22/143 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV53101747; called by muse, mutect2, varscan2
- FBF1 | c.343C>T p.P115S (on ENST00000586717; = p.P129S on NM_001319193.1) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV59864686; called by muse, mutect2
- FBXO21 | c.875A>G p.Q292R | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as COSV57972475; called by muse, varscan2
- FCRLA | c.950C>A p.P317H (on ENST00000367959; = p.P294H on NM_032738.4) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52685454; called by muse, mutect2, varscan2
- FFAR2 | c.628C>G p.P210A | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.147); catalogued as COSV55832185, COSV55832890; called by muse, mutect2, varscan2
- FGG | c.252A>C p.K84N | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV60195463; called by muse, mutect2
- FHDC1 | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as rs147950044, COSV99470954; called by muse, mutect2, varscan2
- FKBPL | c.880del p.V294Lfs*22 | Frame Shift Del (DEL) | VAF 17/133 reads (13%) | catalogued as rs757166166; called by mutect2, pindel, varscan2
- FLG | c.2452C>G p.Q818E | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as rs147738817; called by muse, mutect2, varscan2
- FLG2 | c.2954C>G p.S985C | Missense Mutation (SNP) | VAF 63/510 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.79); catalogued as COSV66168120; called by muse, mutect2, varscan2
- FNDC7 | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1199434194, COSV54752673; called by muse, mutect2, varscan2
- FOCAD | c.3555+2T>C p.X1185_splice | Splice Site (SNP) | VAF 3/24 reads (13%) | catalogued as COSV58097537; called by muse, mutect2
- FOXD3 | c.536G>A p.R179K | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.19); catalogued as COSV64379915; called by muse, mutect2, varscan2
- FOXJ3 | c.1315G>T p.A439S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as COSV62361947; called by muse, mutect2, varscan2
- FOXL1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV57213590; called by muse, mutect2, varscan2
- FREM2 | c.385T>G p.C129G | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54835363; called by mutect2, varscan2
- FRMPD2 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.266); catalogued as rs768263075, COSV59717309; called by muse, mutect2, varscan2
- FSCB | c.1746A>C p.E582D | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.245); catalogued as COSV61217666; called by muse, mutect2, varscan2
- FTSJ3 | c.1336T>C p.F446L | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs757503012, COSV63789953; called by muse, mutect2, varscan2
- FUBP3 | c.1208G>A p.R403Q | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1403389562, COSV60513903; called by muse, mutect2, varscan2
- GALNT16 | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs376979631, COSV61885368; called by muse, mutect2, varscan2
- GALNT16 | c.956dup p.E320Rfs*4 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | catalogued as rs763094427; called by mutect2, varscan2
- GASK1B | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56706510; called by muse, mutect2, varscan2
- GBF1 | c.4557G>T p.E1519D (on ENST00000369983 / NM_001377137.1; = p.E1518D on NM_004193.3) | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.683); catalogued as COSV100890486; called by muse, mutect2
- GGT1 | c.1563+2T>C p.X521_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | catalogued as COSV50639740; called by muse, mutect2, varscan2
- GJB3 | c.568T>A p.F190I | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.673); catalogued as COSV64904530; called by muse, mutect2, varscan2
- GLRX3 | c.240T>A p.Y80* | Nonsense Mutation (SNP) | VAF 19/79 reads (24%) | catalogued as COSV58692399; called by muse, mutect2, varscan2
- GNAZ | c.890A>T p.Y297F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.982); catalogued as COSV50737703; called by muse, mutect2, varscan2
- GOLGA5 | c.543C>T p.H181= | Splice Region (SNP) | VAF 17/132 reads (13%) | catalogued as rs370774857; called by muse, mutect2, varscan2
- GPATCH8 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV59194407; called by muse, mutect2, varscan2
- GPM6B | c.609A>C p.K203N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV57422068; called by muse, mutect2, varscan2
- GPR12 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67344271, COSV67344625; called by muse, mutect2, varscan2
- GPR20 | c.928G>T p.G310C | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV66684315; called by muse, mutect2, varscan2
- GPR61 | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs970434273, COSV100879910, COSV63983640; called by muse, varscan2
- GRB10 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV60009740; called by muse, mutect2, varscan2
- GRID1 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV60024937; called by muse, mutect2, varscan2
- GRIN2B | c.3797C>T p.P1266L | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.058); catalogued as rs201947553, COSV101662965; ClinVar: likely benign; called by muse, mutect2, varscan2
- GRIN2B | c.1607T>G p.V536G | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV74205636; called by muse, mutect2, varscan2
- GRIN2B | c.455A>C p.Q152P | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV74205637; called by muse, mutect2
- GRM2 | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.075); catalogued as rs1207998527, COSV56584019; called by muse, mutect2, varscan2
- GTF3C5 | c.1057G>A p.V353I | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1183963215, COSV59599668; called by muse, mutect2, varscan2
- GUCY2D | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs200637525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GUF1 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55782282; called by muse, mutect2, varscan2
- H2AC12 | c.22G>T p.G8C | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); catalogued as COSV63616905; called by muse, mutect2, varscan2
- HCFC1 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV60071595; called by muse, varscan2
- HCN3 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.005); catalogued as rs765937571, COSV64233784; called by muse, mutect2, varscan2
- HDAC1 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as COSV65190894; called by muse, mutect2, varscan2
- HECW2 | c.2837A>G p.N946S | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV53657105; called by muse, mutect2, varscan2
- HIF3A | c.980G>A p.R327Q (on ENST00000377670 / NM_152795.4; = p.R258Q on NM_022462.4) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs1227145320, COSV52197630; called by muse, mutect2, varscan2
- HIRA | c.1741G>T p.A581S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV54274322; called by muse, mutect2, varscan2
- HKDC1 | c.1836+1G>T p.X612_splice | Splice Site (SNP) | VAF 16/129 reads (12%) | catalogued as COSV63576670, COSV63578863; called by muse, mutect2, varscan2
- HPS5 | c.986-1G>T p.X329_splice (on ENST00000349215 / NM_181507.2; = p.X215_splice on NM_007216.4) | Splice Site (SNP) | VAF 10/78 reads (13%) | catalogued as COSV61687402; called by muse, mutect2
- HSPG2 | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs145847147; called by muse, mutect2, varscan2
- HYDIN | c.10202C>T p.P3401L | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV101156086; called by muse, varscan2
- IFNA7 | c.383G>T p.G128V | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV53330425; called by muse, mutect2
- IGHV3-23 | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 45/434 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs782264567; called by muse, mutect2, varscan2
- IGSF10 | c.5753T>C p.I1918T | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56784344; called by muse, mutect2, varscan2
- IL6ST | c.617A>C p.K206T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.204); catalogued as COSV61140890; called by muse, mutect2
- INHBC | c.1005C>G p.N335K | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV59004970; called by muse, mutect2
- INSM2 | c.1592C>T p.P531L | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV51881240; called by muse, mutect2, varscan2
- INTS11 | c.365C>G p.T122S | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.086); catalogued as COSV60088052; called by muse, mutect2, varscan2
- INTS12 | c.275T>G p.V92G | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as COSV60862114; called by muse, mutect2, varscan2
- INTS6 | c.386C>G p.T129S | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV60877714; called by muse, mutect2, varscan2
- IPCEF1 | c.991C>T p.R331* | Nonsense Mutation (SNP) | VAF 14/234 reads (6%) | catalogued as rs754352746, COSV54543358; called by muse, mutect2
- IQGAP2 | c.652G>T p.V218F | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57172222; called by muse, mutect2, varscan2
- ITPK1 | c.163G>T p.V55F | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50894933; called by muse, mutect2, varscan2
- JAK1 | c.1016del p.N339Ifs*3 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs1181132297; called by mutect2, pindel, varscan2
- JARID2 | c.2206C>A p.P736T | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59188494; called by muse, mutect2, varscan2
- KANSL1 | c.1061T>A p.L354* | Nonsense Mutation (SNP) | VAF 12/164 reads (7%) | catalogued as COSV52267512; called by muse, mutect2
- KCNA6 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.014); catalogued as rs770209419, COSV54974883; called by muse, mutect2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 16/94 reads (17%) | catalogued as rs752059864; called by mutect2, varscan2
- KCTD3 | c.2172T>A p.S724R | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV52066080; called by muse, varscan2
- KDM5A | c.2086C>T p.R696W | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV66990078; called by muse, mutect2, varscan2
- KDM6B | c.3718G>A p.E1240K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.167); catalogued as COSV54680606; called by muse, mutect2
- KDR | c.3047T>A p.M1016K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55763113; called by muse, mutect2
- KIF18A | c.1570C>G p.Q524E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV54182673, COSV54187207; called by muse, mutect2, varscan2
- KIF21B | c.325G>C p.E109Q | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV59756283; called by muse, mutect2, varscan2
- KIF26B | c.5773G>A p.V1925M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1178212581, COSV63639952; called by muse, mutect2, varscan2
- KIRREL1 | c.1232T>C p.V411A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV63286607; called by muse, mutect2, varscan2
- KRCC1 | c.547del p.S183Afs*7 | Frame Shift Del (DEL) | VAF 23/116 reads (20%) | catalogued as rs1326358542; called by mutect2, varscan2
- KRT31 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs772110327, COSV52434596; called by muse, mutect2, varscan2
- KRT6A | c.611A>C p.K204T | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV100416987; called by muse, mutect2
- KRT71 | c.307C>A p.H103N | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV57290255; called by muse, mutect2, varscan2
- KRT80 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV57548683; called by muse, mutect2, varscan2
- KRTAP9-4 | c.348C>A p.C116* | Nonsense Mutation (SNP) | VAF 62/242 reads (26%) | catalogued as COSV61897925, COSV61898619; called by muse, mutect2, varscan2
- LAMA1 | c.8128G>A p.V2710I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs958888771, COSV67535747; called by muse, mutect2, varscan2
- LAMA1 | c.2431G>A p.G811R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.055); catalogued as rs754763523, COSV67535751; called by mutect2, varscan2
- LENG8 | c.949C>A p.L317I | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58727255; called by muse, mutect2, varscan2
- LHFPL4 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55001919; called by muse, mutect2, varscan2
- LIG3 | c.1822A>T p.R608* | Nonsense Mutation (SNP) | VAF 20/149 reads (13%) | catalogued as COSV52007101; called by muse, mutect2, varscan2
- LPXN | c.824G>C p.R275P | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV67716853; called by muse, mutect2, varscan2
- LRBA | c.506T>A p.L169Q | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV63953744; called by muse, mutect2, varscan2
- LRMDA | c.464A>G p.E155G | Missense Mutation (SNP) | VAF 5/115 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV100994827; called by muse, mutect2
- LRP1B | c.8622T>A p.H2874Q | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.112); catalogued as COSV67209117; called by muse, mutect2, varscan2
- LRP2 | c.5272G>C p.G1758R | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55550274; called by muse, mutect2, varscan2
- LRP6 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs371768750; called by muse, mutect2
- LRRC4 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0.003); catalogued as rs1046822930, COSV50813736; called by muse, mutect2, varscan2
- LRRC8C | c.2216del p.N739Tfs*19 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | catalogued as COSV65001046; called by mutect2, pindel, varscan2
- LRRIQ1 | c.3362A>T p.Q1121L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67829571; called by muse, mutect2, varscan2
- LRRK2 | c.1047G>A p.W349* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as COSV54150609; called by muse, mutect2, varscan2
- LTBP4 | c.1401C>G p.Y467* (on ENST00000308370 / NM_001042544.1; = p.Y430* on NM_003573.2) | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV52580317; called by muse, mutect2, varscan2
- LZTS2 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV64651429; called by muse, mutect2, varscan2
- MAGEL2 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs372275206; called by muse, mutect2, varscan2
- MAP2 | c.4067G>T p.R1356I | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as rs754124367, COSV99559966; called by muse, mutect2, varscan2
- MAP3K4 | c.2002T>C p.Y668H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62332689; called by muse, mutect2, varscan2
- MAP3K4 | c.2858C>T p.A953V | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs1420558020, COSV62332699; called by muse, mutect2, varscan2
- MAPK8 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs759178320, COSV64408861; called by muse, mutect2, varscan2
- MASTL | c.1390del p.T464Lfs*3 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | catalogued as rs1355602467; called by mutect2, pindel, varscan2
- MCM3 | c.1916C>T p.A639V (on ENST00000229854 / NM_001366374.2; = p.A629V on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772883621, COSV57716362; called by muse, mutect2, varscan2
- MDGA1 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as rs373379741, COSV51796299; called by muse, mutect2, varscan2
- MDN1 | c.7292G>A p.G2431D | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV65520665; called by muse, mutect2, varscan2
- MFSD1 | c.1384T>C p.S462P | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as COSV51838847; called by muse, mutect2, varscan2
- MICAL1 | c.1312A>C p.S438R | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62193127; called by muse, mutect2, varscan2
- MICU3 | c.1123G>C p.E375Q | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV58845421, COSV58845800; called by muse, mutect2
- MLLT10 | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV56994628; called by muse, mutect2, varscan2
- MORF4L2 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100846373; called by muse, mutect2, varscan2
- MRPL9 | c.696A>T p.R232S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV58618026; called by muse, mutect2, varscan2
- MUC17 | c.2536T>C p.S846P | Missense Mutation (SNP) | VAF 98/590 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV60286433; called by muse, mutect2, varscan2
- MUC5B | c.15437T>C p.V5146A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.901); catalogued as COSV71591585; called by muse, mutect2, varscan2
- MUCL3 | c.1103C>A p.P368H (on ENST00000304311; = p.P1244H on NM_080870.4) | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV58517024; called by muse, mutect2, varscan2
- MYH1 | c.4022G>A p.R1341H | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs758259998, COSV56846986, COSV99874907; called by muse, mutect2, varscan2
- MYO16 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775114035, COSV51789356; called by muse, mutect2, varscan2
- MYO18A | c.2327A>T p.K776M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62865428; called by muse, mutect2, varscan2
- MYO3A | c.1762G>A p.G588S | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776219381, COSV56327910; called by muse, mutect2
- MYOM2 | c.4340del p.P1447Rfs*65 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs1237303800, COSV50718652; called by mutect2, pindel, varscan2
- NAALADL1 | c.551T>G p.L184R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV60523641; called by muse, mutect2, varscan2
- NBEAL2 | c.6175C>A p.L2059M | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV52756785; called by muse, mutect2, varscan2
- NBPF3 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 36/199 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.213); catalogued as rs1269995240, COSV59058584; called by muse, mutect2, varscan2
- NCAPD2 | c.2508del p.F837Sfs*36 | Frame Shift Del (DEL) | VAF 11/90 reads (12%) | catalogued as rs772347389; called by mutect2, varscan2
- NCOA1 | c.1064A>C p.Q355P | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.031); catalogued as COSV56042622; called by muse, mutect2, varscan2
- NELL2 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV61573271; called by muse, mutect2, varscan2
- NINL | c.2867G>A p.R956Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777373823, COSV54001408; called by muse, mutect2, varscan2
- NIPBL | c.8326del p.I2776Lfs*3 | Frame Shift Del (DEL) | VAF 13/62 reads (21%) | catalogued as rs1157335847; called by mutect2, pindel, varscan2
- NLGN1 | c.1786G>C p.E596Q | Missense Mutation (SNP) | VAF 20/131 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV64330891; called by muse, mutect2, varscan2
- NLRP12 | c.97G>T p.G33W | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV60746327; called by muse, mutect2, varscan2
- NLRP13 | c.1871G>C p.G624A | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV61621290; called by muse, mutect2, varscan2
- NLRP7 | c.794T>C p.L265P | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60173497; called by muse, mutect2, varscan2
- NOP14 | c.329A>C p.Q110P | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100054642; called by muse, mutect2
- NOS1AP | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs1485553225, COSV100722803; called by muse, mutect2
- NPR2 | c.2720C>T p.T907M | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1311857509, CM124978, COSV52413915; called by muse, mutect2, varscan2
- NR1I2 | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV61978105; called by muse, mutect2
- NR4A3 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1159997688, COSV58243100; called by muse, varscan2
- NRDE2 | c.268del p.R90Gfs*69 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs1249617548, COSV62963847; called by mutect2, varscan2
- NT5DC2 | c.563T>A p.F188Y | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV58735175; called by muse, mutect2, varscan2
- NTN3 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53546126; called by muse, mutect2, varscan2
- NUP133 | c.2889C>G p.Y963* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as COSV54570397; called by muse, mutect2, varscan2
- OAS3 | c.949G>C p.A317P | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57445282, COSV57446373; called by muse, mutect2, varscan2
- OBI1 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 16/135 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV56145371; called by muse, mutect2, varscan2
- OCIAD1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 15/80 reads (19%) | catalogued as rs772791631, COSV51900572; called by muse, mutect2, varscan2
- OGDH | c.1288C>T p.P430S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56048752; called by muse, mutect2, varscan2
- OPA1 | c.496G>C p.A166P | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.116); catalogued as rs1018313517, COSV62480105; called by muse, mutect2
- OR14K1 | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV51720294, COSV99314976, COSV99315195; called by muse, mutect2
- OR2AT4 | c.834G>T p.M278I | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as COSV59406838; called by muse, mutect2, varscan2
- OR51G1 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV58969012; called by muse, mutect2, varscan2
- OR51S1 | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.754); catalogued as COSV59058132; called by muse, mutect2, varscan2
- OR5M10 | c.393T>G p.H131Q | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV73242297; called by muse, mutect2, varscan2
- OR5M8 | c.631T>C p.F211L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59116533; called by muse, mutect2, varscan2
- OR8B4 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs371189371, COSV62069699; called by muse, mutect2, varscan2
- OR8K1 | c.336T>G p.I112M | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.007); catalogued as COSV54402232; called by muse, mutect2, varscan2
- PACSIN2 | c.718C>T p.R240C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369727314; called by muse, mutect2, varscan2
- PARP3 | c.1343G>C p.R448T | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.153); catalogued as COSV67168366; called by muse, mutect2, varscan2
- PAX3 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 32/169 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.623); catalogued as COSV60587875; called by muse, mutect2, varscan2
- PCBP4 | c.859C>T p.R287W (on ENST00000322099 / NM_033010.2; = p.R244W on NM_020418.4) | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1471682615, COSV59053702; called by muse, mutect2, varscan2
- PCDH12 | c.3125G>A p.S1042N | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs953533033, COSV51520908; called by muse, mutect2, varscan2
- PCDH18 | c.1691T>G p.L564R | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61267826; called by muse, mutect2, varscan2
- PCDH9 | c.2483T>C p.V828A | Missense Mutation (SNP) | VAF 27/149 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV60544235; called by muse, mutect2, varscan2
- PCDHA12 | c.1610C>T p.A537V | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV56484482; called by muse, mutect2, varscan2
- PCDHAC1 | c.1522A>G p.T508A | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV53846607; called by muse, mutect2, varscan2
- PCDHB1 | c.2332T>A p.F778I | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.643); catalogued as COSV60629503, COSV60630499; called by muse, mutect2, varscan2
- PCDHB13 | c.1129G>T p.G377* | Nonsense Mutation (SNP) | VAF 17/169 reads (10%) | catalogued as COSV53395590, COSV53402238; called by muse, mutect2, varscan2
- PCDHB15 | c.615G>T p.Q205H | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.964); catalogued as COSV50897353; called by muse, mutect2, varscan2
- PCDHB2 | c.1369T>C p.S457P | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as COSV50569845; called by muse, varscan2
- PCDHB6 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.958); catalogued as COSV50689744; called by muse, mutect2, varscan2
- PCDHB8 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.226); catalogued as COSV50763046; called by muse, mutect2, varscan2
- PCDHGA6 | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.308); catalogued as COSV53933229; called by muse, mutect2, varscan2
- PCDHGB3 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs781345070, COSV53933204; called by muse, mutect2, varscan2
- PCLO | c.4969G>C p.V1657L | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV61620266, COSV61629782; called by muse, mutect2, varscan2
- PCSK5 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs952482391, COSV65087849; called by muse, mutect2, varscan2
- PDE6C | c.760C>G p.L254V | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV65115579; called by muse, mutect2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 9/37 reads (24%) | catalogued as rs747131399; called by mutect2, varscan2
- PEG3 | c.1706A>C p.K569T | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55628435; called by muse, mutect2, varscan2
- PEX7 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV59249051; called by muse, mutect2, varscan2
- PGC | c.991C>G p.P331A | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV57824579; called by muse, mutect2
- PGGHG | c.1034A>C p.K345T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV67140696; called by muse, mutect2, varscan2
- PGM2 | c.1220A>G p.N407S | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.255); catalogued as COSV67938662; called by muse, mutect2, varscan2
- PHACTR1 | c.759del p.P254Qfs*59 | Frame Shift Del (DEL) | VAF 11/108 reads (10%) | catalogued as rs749326031; called by mutect2, pindel, varscan2
- PHB | c.689C>G p.T230S | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55930891; called by muse, mutect2
- PHF11 | c.570G>T p.Q190H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.862); catalogued as COSV62896407; called by muse, mutect2, varscan2
- PHF20L1 | c.2126G>T p.C709F | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55191627; called by muse, mutect2, varscan2
- PHGDH | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV101025110, COSV65570344; called by muse, mutect2, varscan2
- PHLDB2 | c.1688G>A p.S563N | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV67310527; called by muse, mutect2, varscan2
- PICALM | c.407T>C p.V136A | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as COSV62670345; called by muse, mutect2, varscan2
- PIGT | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754396962, COSV54125944, COSV54127848; called by muse, mutect2, varscan2
- PIMREG | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs752671456, COSV51470712; called by mutect2, varscan2
- PITPNM1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as rs1286920438, COSV62707572; called by muse, mutect2, varscan2
- PKHD1L1 | c.4777C>A p.P1593T | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65741680; called by muse, mutect2, varscan2
- PKLR | c.1109C>T p.A370V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100712904; called by muse, mutect2
- PLA2G2E | c.100A>C p.K34Q | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV64290464; called by muse, mutect2, varscan2
- PLA2G4F | c.2287T>G p.F763V | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51826443; called by muse, mutect2, varscan2
- PLCD4 | c.22C>T p.Q8* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | catalogued as rs1265137456, COSV68842473; called by muse, mutect2, varscan2
- PLRG1 | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57423308; called by muse, mutect2
- POLDIP2 | c.1016C>G p.P339R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.381); catalogued as COSV50228349; called by muse, mutect2, varscan2
- POLE | c.5842G>T p.D1948Y | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs748652801, COSV57678684; called by muse, mutect2, varscan2
- POLE | c.4556G>A p.R1519H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); catalogued as rs376530977, COSV57693617; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR1A | c.640G>A p.V214I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs537206211, COSV55692002; called by muse, mutect2, varscan2
- POM121L12 | c.758C>A p.P253H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV68692722, COSV68692753; called by muse, mutect2, varscan2
- POP1 | c.2254del p.T752Lfs*12 | Frame Shift Del (DEL) | VAF 23/119 reads (19%) | catalogued as rs868622083, COSV62893071; called by mutect2, pindel, varscan2
- PPP1R13B | c.2638C>T p.H880Y | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV52450772; called by muse, mutect2
- PPP1R13L | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763548265, COSV62908353; called by muse, mutect2, varscan2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | catalogued as rs764112302; called by mutect2, varscan2
- PRKD2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.674); catalogued as rs752855161, COSV52186092; called by muse, mutect2, varscan2
- PRKDC | c.10798C>A p.P3600T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV58050010; called by muse, mutect2, varscan2
- PRPF6 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV53869313; called by muse, mutect2
- PRUNE2 | c.4205A>G p.E1402G | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs1324609685, COSV65040727; called by muse, mutect2, varscan2
- PSD4 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs139776921, COSV55526043; called by muse, mutect2
- PSME4 | c.5413del p.T1805Pfs*69 | Frame Shift Del (DEL) | VAF 29/114 reads (25%) | catalogued as COSV101122574; called by mutect2, varscan2
- PTCD1 | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs150731740; called by muse, mutect2, varscan2
- PTPN14 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs139895368; called by muse, mutect2, varscan2
- PTPRT | c.872C>A p.P291H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100627301; called by muse, mutect2, varscan2
- RAD1 | c.161A>G p.E54G | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57715077; called by muse, mutect2, varscan2
- RAF1 | c.955G>A p.A319T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.334); catalogued as rs749989518, COSV52578826, COSV52579717; called by muse, mutect2, varscan2
- RBBP8 | c.2302C>G p.Q768E | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV59090864; called by muse, mutect2, varscan2
- RBL1 | c.431del p.L144* | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as COSV60328025; called by mutect2, varscan2
- REG1B | c.443A>C p.K148T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV59305192, COSV59308220; called by muse, mutect2, varscan2
- RFFL | c.1084C>T p.R362W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs550307820, COSV52071414; called by muse, mutect2, varscan2
- RFNG | c.663-3del | Splice Region (DEL) | VAF 5/36 reads (14%) | catalogued as rs1197699009; called by mutect2, pindel, varscan2
- RGS22 | c.1051G>T p.V351L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as rs777251698, COSV62660774; called by muse, mutect2, varscan2
- RHEX | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV58980160; called by muse, mutect2, varscan2
- RHOBTB3 | c.1502A>G p.Y501C | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66101860; called by muse, mutect2, varscan2
- RHPN2 | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV54276202; called by muse, mutect2, varscan2
- RIMS4 | c.567G>C p.E189D | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.123); catalogued as COSV65719590, COSV65720739; called by muse, varscan2
- RNASE9 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs773490266, COSV58880339; called by muse, mutect2, varscan2
- RNF125 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs779097194, COSV54184290; called by muse, mutect2, varscan2
- RNF180 | c.878A>G p.Q293R | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV56961479; called by muse, mutect2
- RNF26 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs922686448, COSV60990308; called by muse, mutect2
- RPH3A | c.1120C>A p.P374T (on ENST00000389385 / NM_001143854.2; = p.P370T on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV66990800; called by muse, mutect2, varscan2
- RPS6KB2 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 56/297 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57049187; called by muse, varscan2
- RREB1 | c.895C>G p.Q299E | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV58556778; called by muse, mutect2
- RSBN1L | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1457449108, COSV58507804; called by muse, mutect2, varscan2
- RTN4R | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV50380621; called by muse, mutect2, varscan2
- RWDD2B | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54501395; called by muse, mutect2, varscan2
- RYR2 | c.10003T>C p.S3335P | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.418); catalogued as COSV63680480; called by muse, mutect2, varscan2
- SAMSN1 | c.919A>C p.I307L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV53470386; called by muse, mutect2, varscan2
- SBF2 | c.2164C>T p.R722C | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753111342, COSV56297289; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCMH1 | c.206C>A p.P69H (on ENST00000326197 / NM_001031694.2; = p.P22H on NM_012236.4) | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58232577; called by muse, mutect2, varscan2
- SCUBE2 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs370871651; called by muse, mutect2, varscan2
- SCYL3 | c.2108del p.K703Rfs*7 (on ENST00000367770; = p.K649Rfs*7 on NM_020423.7) | Frame Shift Del (DEL) | VAF 17/95 reads (18%) | catalogued as rs1558112386; called by mutect2, pindel, varscan2
- SDCCAG8 | c.1085A>C p.D362A | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.05); catalogued as COSV59408054; called by muse, varscan2
- SEC22A | c.97T>C p.C33R | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.216); catalogued as COSV59371824; called by muse, mutect2
- SEC23A | c.2138G>A p.S713N | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56973259; called by muse, mutect2, varscan2
- SEC23A | c.1696A>C p.S566R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV56973279; called by muse, mutect2, varscan2
- SEC23B | c.1157A>G p.Q386R | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.463); catalogued as CM094624, COSV52719821; called by muse, mutect2, varscan2
- SEC31A | c.1511T>C p.I504T | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV52344638; called by muse, mutect2, varscan2
- SECTM1 | c.68C>A p.A23D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as COSV99486231; called by muse, mutect2, varscan2
- SEMA7A | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV56089845; called by muse, mutect2, varscan2
- SERPING1 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1565171840, COSV53542267; called by muse, mutect2, varscan2
- SERTAD4 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as rs1325733185, COSV65399210; called by muse, mutect2
- SFMBT2 | c.2003del p.R668Kfs*163 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as COSV62811742; called by mutect2, pindel, varscan2
- SGIP1 | c.1397C>A p.P466Q | Missense Mutation (SNP) | VAF 31/251 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV52766826; called by muse, mutect2, varscan2
- SGPP2 | c.276T>G p.F92L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV58328470; called by muse, mutect2, varscan2
- SIGLEC9 | c.608A>C p.Q203P | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as COSV51583821; called by muse, mutect2, varscan2
- SIM1 | c.2215T>A p.F739I | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as COSV53491237, COSV53496167; called by muse, mutect2, varscan2
- SIX5 | c.1680G>C p.K560N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV52177388; called by muse, mutect2
- SLC17A6 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as rs951206391, COSV54135643; called by muse, mutect2, varscan2
- SLC1A1 | c.1051G>A p.D351N | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV52052386; called by muse, mutect2, varscan2
- SLC24A2 | c.930G>T p.K310N | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.544); catalogued as COSV53863195; called by muse, mutect2, varscan2
- SLC27A3 | c.1084G>T p.A362S (on ENST00000271857; = p.A234S on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/133 reads (17%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.542); catalogued as rs752328083, COSV55163219; called by muse, mutect2, varscan2
- SLC30A1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV65360907; called by muse, mutect2
- SLC36A2 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV58865386; called by muse, mutect2, varscan2
- SLC38A10 | c.2095G>A p.A699T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV55844808; called by muse, mutect2, varscan2
- SLC4A11 | c.2324C>T p.P775L | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as COSV66261531; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1906C>T p.H636Y (on ENST00000540229 / NM_001371097.1; = p.H575Y on NM_001009562.4) | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as COSV67443049; called by muse, mutect2
- SMAD9 | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.017); catalogued as COSV63204785; called by muse, mutect2, varscan2
- SMC1B | c.2845G>T p.D949Y | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV62529622; called by muse, mutect2, varscan2
- SMC5 | c.2556_2558del p.S853del | In Frame Del (DEL) | VAF 26/171 reads (15%) | catalogued as rs1199537290; called by pindel, varscan2
- SMCR8 | c.953A>C p.K318T | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV58176813; called by muse, mutect2, varscan2
- SNX33 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.022); catalogued as COSV57913359; called by muse, mutect2, varscan2
- SOX10 | c.778G>A p.G260R | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.581); catalogued as rs367743809; called by muse, mutect2, varscan2
- SPATA17 | c.1006-2A>G p.X336_splice | Splice Site (SNP) | VAF 36/141 reads (26%) | catalogued as rs372001938; called by muse, mutect2, varscan2
- SPEF2 | c.2245A>G p.T749A | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as COSV61547444; called by muse, mutect2, varscan2
- SPEN | c.4351G>A p.A1451T | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV65360880; called by muse, mutect2
- SPTB | c.1746C>A p.D582E | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs766762166, COSV67631198; called by muse, mutect2, varscan2
- SRD5A1 | c.243C>G p.S81R | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV52953848; called by muse, mutect2, varscan2
- SRGAP3 | c.1464G>T p.Q488H | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.598); catalogued as COSV64532520; called by muse, mutect2, varscan2
- ST8SIA6 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 52/272 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.617); catalogued as COSV66467707, COSV66471803; called by muse, mutect2, varscan2
- SULF2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs549518880, COSV63414827, COSV63419062; called by muse, mutect2, varscan2
- SVEP1 | c.3410A>C p.K1137T | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as COSV57034385; called by muse, mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | catalogued as rs570102997; called by mutect2, varscan2
- SYDE1 | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.082); catalogued as COSV54619063; called by muse, mutect2, varscan2
- SYNE1 | c.16496A>T p.K5499M (on ENST00000367255 / NM_182961.4; = p.K5428M on NM_033071.3) | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV54936582, COSV54962906, COSV99555537; called by muse, mutect2, varscan2
- TACC2 | c.6446dup p.V2150Sfs*10 (on ENST00000334433; = p.V228Sfs*10 on NM_006997.4) | Frame Shift Ins (INS) | VAF 26/162 reads (16%) | catalogued as rs759725298; called by mutect2, varscan2
- TADA3 | c.329C>G p.A110G | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55028450; called by muse, mutect2, varscan2
- TALDO1 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 32/143 reads (22%) | catalogued as COSV59797403; called by muse, mutect2, varscan2
- TAS1R3 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1334417483, COSV100229936, COSV59563050; called by mutect2, varscan2
- TBC1D17 | c.286C>T p.R96W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); catalogued as rs756084780, COSV55578199; called by muse, mutect2, varscan2
- TBPL1 | c.352C>A p.P118T | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV51599576; called by muse, mutect2, varscan2
- TBX1 | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.795); catalogued as COSV100284207; called by muse, varscan2
- TEKT1 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as COSV58622923; called by muse, mutect2, varscan2
- TENM2 | c.1430A>G p.Q477R (on ENST00000518659 / NM_001122679.2; = p.Q245R on NM_001080428.3) | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV69128240; called by muse, mutect2, varscan2
- TERF2 | c.1466del p.K489Sfs*6 | Frame Shift Del (DEL) | VAF 12/87 reads (14%) | catalogued as COSV99651609; called by mutect2, pindel, varscan2
- TESK2 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV59151372; called by muse, mutect2, varscan2
- TET2 | c.835A>C p.T279P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV99482890; called by muse, mutect2
- TFB1M | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.024); catalogued as rs927033222, COSV65698898; called by muse, mutect2, varscan2
- TGFBI | c.752A>G p.D251G | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV59350899; called by muse, mutect2
- THRA | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.099); catalogued as COSV99225508; called by muse, mutect2
- TIE1 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.402); catalogued as rs200415018, COSV65249337; called by muse, mutect2, varscan2
- TIE1 | c.1942del p.R648Dfs*15 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as COSV65250259; called by mutect2, varscan2
- TLL1 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757327489, COSV50274451; called by muse, mutect2, varscan2
- TMEM198 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as rs778908149, COSV54717549; called by muse, mutect2
- TMEM67 | c.1645C>T p.R549C | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747025617, CM114284, COSV60038483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMPRSS11F | c.986T>C p.V329A | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62466078; called by muse, mutect2
- TMPRSS15 | c.2429G>T p.C810F | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53038700, COSV53047047; called by muse, mutect2, varscan2
- TNRC18 | c.8464G>A p.G2822R | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342472551, COSV100078942, COSV60307185; called by muse, mutect2, varscan2
- TOGARAM1 | c.3016A>G p.T1006A | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1403560891, COSV63891659; called by muse, mutect2, varscan2
- TRERF1 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as COSV61670519; called by muse, mutect2, varscan2
- TRIM55 | c.1438C>T p.R480W | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.153); catalogued as rs754147349, COSV52545616; called by muse, mutect2, varscan2
- TRIO | c.3138G>T p.K1046N | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60082291; called by muse, mutect2, varscan2
- TRIP13 | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.517); catalogued as rs951037088, COSV51319738; called by muse, mutect2, varscan2
- TRIP6 | c.1085G>C p.C362S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.438); catalogued as COSV52341609; called by muse, mutect2, varscan2
- TRRAP | c.11209G>T p.E3737* (on ENST00000359863 / NM_001244580.1; = p.E3708* on NM_003496.3) | Nonsense Mutation (SNP) | VAF 19/96 reads (20%) | catalogued as COSV62815992; called by muse, mutect2, varscan2
- TRUB2 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.153); catalogued as rs745588527, COSV65759573; called by mutect2, varscan2
- TSKU | c.301C>G p.P101A | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.572); catalogued as COSV60751417; called by muse, mutect2, varscan2
- TSPYL2 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1556807960, COSV60234543; called by muse, mutect2, varscan2
- TSPYL6 | c.176T>C p.V59A | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as COSV57814057; called by muse, mutect2, varscan2
- TTN | c.89740C>T p.R29914C (on ENST00000591111; = p.R22490C on NM_003319.4) | Missense Mutation (SNP) | VAF 9/65 reads (14%) | PolyPhen probably damaging (0.998); catalogued as rs757099797, COSV60002267; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.86476C>T p.R28826C (on ENST00000591111; = p.R21402C on NM_003319.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | PolyPhen possibly damaging (0.897); catalogued as rs775591945, COSV59954852; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.57253A>T p.T19085S (on ENST00000591111; = p.T11661S on NM_003319.4) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | PolyPhen possibly damaging (0.708); catalogued as COSV60002385; called by muse, mutect2, varscan2
- TTN | c.43365A>C p.E14455D (on ENST00000591111; = p.E7031D on NM_003319.4) | Missense Mutation (SNP) | VAF 22/150 reads (15%) | PolyPhen benign (0.006); catalogued as COSV60002425; called by muse, mutect2, varscan2
- TTN | c.19099T>C p.S6367P (on ENST00000591111; = p.S5440P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | PolyPhen benign (0.041); catalogued as COSV60002455; called by muse, mutect2, varscan2
- TTN | c.16133A>G p.Q5378R (on ENST00000591111; = p.Q4451R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/113 reads (19%) | PolyPhen benign (0.007); catalogued as COSV60002671; called by muse, mutect2, varscan2
- TTR | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.038); catalogued as rs267607159, CM900217, CM973044, COSV52701391; ClinVar: uncertain significance; called by mutect2, varscan2
- TUBA3C | c.1109A>C p.K370T | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV68028132; called by muse, mutect2, varscan2
- TXNDC11 | c.923C>G p.A308G (on ENST00000356957 / NM_001303447.2; = p.A281G on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV51598425; called by muse, mutect2, varscan2
- TYW1 | c.1489T>G p.F497V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs746373624, COSV62752279; called by muse, mutect2, varscan2
- U2AF1L4 | c.451C>T p.R151W (on ENST00000412391; = p.R112W on NM_001040425.3) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53073864; called by muse, mutect2, varscan2
- UAP1 | c.1535A>G p.N512S (on ENST00000271469 / NM_001324116.1; = p.N495S on NM_003115.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV54850279; called by muse, mutect2
- UBE4A | c.2177T>C p.F726S (on ENST00000252108 / NM_001204077.2; = p.F733S on NM_004788.4) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52803743; called by muse, mutect2, varscan2
- UBQLN3 | c.1145del p.P382Hfs*20 | Frame Shift Del (DEL) | VAF 16/126 reads (13%) | catalogued as COSV61165269; called by pindel, varscan2
- UGT1A4 | c.517del p.W173Gfs*8 | Frame Shift Del (DEL) | VAF 31/170 reads (18%) | catalogued as rs780658532; called by mutect2, pindel, varscan2
- UNC13B | c.2551A>G p.N851D | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs938252783, COSV65933972; called by muse, mutect2, varscan2
- UNCX | c.287C>A p.P96Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.183); catalogued as rs760529225, COSV100310252; called by muse, mutect2
- URGCP | c.496G>A p.A166T (on ENST00000453200 / NM_001077663.3; = p.A157T on NM_017920.4) | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV56246885; called by muse, mutect2, varscan2
- USH2A | c.12028A>G p.T4010A | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs765237520, COSV56359385; called by muse, mutect2, varscan2
- UTP20 | c.392dup p.L131Ffs*27 | Frame Shift Ins (INS) | VAF 30/188 reads (16%) | catalogued as rs761528888; called by mutect2, varscan2
- VAPA | c.160A>G p.T54A | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV61297694; called by muse, mutect2, varscan2
- VPS13B | c.9689G>T p.R3230M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV62139377; called by muse, mutect2, varscan2
- VPS13C | c.6917C>T p.S2306L (on ENST00000644861 / NM_020821.3; = p.S2263L on NM_017684.5) | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV51158568; called by muse, mutect2, varscan2
- VPS45 | c.152T>G p.L51R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64887578; called by muse, mutect2, varscan2
- VPS53 | c.665C>T p.A222V (on ENST00000571805 / NM_001366253.2; = p.A193V on NM_018289.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.409); catalogued as rs138639431; called by mutect2, varscan2
- VSIG2 | c.542G>A p.R181H | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs148389397; called by muse, mutect2, varscan2
- VTA1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV62658685; called by muse, mutect2, varscan2
- VWF | c.2310del p.M771Wfs*30 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | catalogued as rs776747320; called by mutect2, pindel, varscan2
- WAS | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.082); catalogued as COSV100939492; called by muse, mutect2, varscan2
- WASHC2A | c.3999T>A p.D1333E | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99254655; called by muse, mutect2, varscan2
- WDFY3 | c.102G>C p.E34D | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV55699299; called by muse, mutect2, varscan2
- WTAP | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV61610010; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 26/112 reads (23%) | catalogued as rs762052135; called by mutect2, varscan2
- YIPF2 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs774193788, COSV53403320; called by muse, mutect2, varscan2
- ZAN | c.8380G>T p.E2794* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV61808094, COSV61808677; called by muse, mutect2
- ZC3HAV1 | c.2683G>A p.E895K | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV54295129; called by muse, mutect2, varscan2
- ZCCHC4 | c.960del p.F320Lfs*19 | Frame Shift Del (DEL) | VAF 16/87 reads (18%) | catalogued as rs760215323; called by mutect2, pindel, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs745875253; called by mutect2, varscan2
- ZDHHC18 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750634453, COSV65145302; called by muse, mutect2
- ZDHHC8 | c.1369C>G p.P457A | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV57709922; called by muse, mutect2, varscan2
- ZEB2 | c.2603A>T p.E868V | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100356027; called by muse, mutect2, varscan2
- ZEB2 | c.2602G>T p.E868* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as COSV100356031; called by muse, mutect2, varscan2
- ZFHX3 | c.7343G>C p.G2448A | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV51715878; called by muse, mutect2, varscan2
- ZFHX4 | c.6719T>G p.V2240G | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50699474; called by muse, mutect2, varscan2
- ZFP30 | c.235+2T>C p.X79_splice | Splice Site (SNP) | VAF 23/199 reads (12%) | catalogued as COSV63622561; called by muse, mutect2, varscan2
- ZIM3 | c.1150del p.I384Sfs*49 | Frame Shift Del (DEL) | VAF 20/172 reads (12%) | catalogued as rs750173990; called by mutect2, pindel, varscan2
- ZNF121 | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as COSV57551466; called by muse, mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/80 reads (10%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF142 | c.2476G>T p.D826Y (on ENST00000411696 / NM_001379660.1; = p.D626Y on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0.026); catalogued as COSV68745809; called by muse, mutect2
- ZNF143 | c.1724C>G p.T575S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55179668; called by muse, mutect2, varscan2
- ZNF207 | c.280C>G p.R94G | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV58299662; called by muse, mutect2, varscan2
- ZNF30 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.182); catalogued as COSV57853614; called by muse, mutect2
- ZNF304 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56584024; called by muse, mutect2, varscan2
- ZNF329 | c.128A>T p.Q43L | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV63772230; called by muse, mutect2, varscan2
- ZNF358 | c.1627A>G p.T543A | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV51174811; called by muse, mutect2, varscan2
- ZNF558 | c.109A>T p.S37C | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV56862992; called by muse, mutect2, varscan2
- ZNF57 | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0.335); catalogued as COSV60983264; called by muse, mutect2, varscan2
- ZNF582 | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56731927; called by muse, mutect2, varscan2
- ZNF641 | c.907C>T p.R303* | Nonsense Mutation (SNP) | VAF 12/86 reads (14%) | catalogued as rs976947557, COSV56390001; called by muse, mutect2, varscan2
- ZNF701 | c.894del p.K298Nfs*4 (on ENST00000301093; = p.K232Nfs*4 on NM_018260.3) | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | catalogued as rs762217868; called by mutect2, pindel, varscan2
- ZNF781 | c.599T>G p.L200R | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62201140; called by muse, mutect2, varscan2
- ZNF804A | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 14/67 reads (21%) | catalogued as COSV56436947, COSV56445554; called by muse, mutect2, varscan2
- ZNF804B | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60824658; called by muse, mutect2, varscan2
- ZNF827 | c.2611C>G p.L871V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV65226455; called by muse, mutect2
- ZNF831 | c.481A>C p.K161Q | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64039363; called by muse, mutect2, varscan2
- ZSWIM1 | c.698G>C p.W233S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV54846932; called by muse, mutect2, varscan2
- ZWILCH | c.1567T>C p.Y523H | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778981545, COSV57179446; called by muse, mutect2, varscan2
- ZWINT | c.574C>T p.L192F | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV59185197; called by muse, mutect2
- AC024940.1 | n.2223_2227+6del | Splice Site (DEL) | VAF 4/62 reads (6%) | called by mutect2, pindel
- ACVR2A | c.1345dup p.A449Gfs*8 | Frame Shift Ins (INS) | VAF 27/121 reads (22%) | called by pindel, varscan2
- AGPAT4 | c.216_233del p.E72_T77del | In Frame Del (DEL) | VAF 7/63 reads (11%) | called by mutect2, pindel
- AHDC1 | c.1758del p.K586Nfs*37 | Frame Shift Del (DEL) | VAF 16/68 reads (24%) | called by mutect2, pindel, varscan2
- AMER1 | c.408_450del p.L137Qfs*19 | Frame Shift Del (DEL) | VAF 10/47 reads (21%) | called by mutect2, pindel
- ANLN | c.1428del p.K476Nfs*13 | Frame Shift Del (DEL) | VAF 24/178 reads (13%) | called by mutect2, varscan2
- AOC1 | c.475_482del p.T159Pfs*18 | Frame Shift Del (DEL) | VAF 10/95 reads (11%) | called by mutect2, pindel
- APOBR | c.2837del p.P946Lfs*39 (on ENST00000431282; = p.P955Lfs*39 on NM_018690.4) | Frame Shift Del (DEL) | VAF 3/18 reads (17%) | called by mutect2, pindel
- ARRDC3 | c.233_235del p.E78del | In Frame Del (DEL) | VAF 14/124 reads (11%) | called by pindel, varscan2
- ATAD2 | c.1311_1316del p.L438_K439del | In Frame Del (DEL) | VAF 22/179 reads (12%) | called by mutect2, pindel, varscan2
- ATAD2 | c.1201del p.Y401Ifs*5 | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- ATXN2L | c.1907del p.P636Rfs*19 | Frame Shift Del (DEL) | VAF 9/95 reads (9%) | called by mutect2, pindel, varscan2
- B3GNT2 | c.107dup p.N36Kfs*64 | Frame Shift Ins (INS) | VAF 26/150 reads (17%) | called by mutect2, varscan2
- BAG6 | c.344del p.P115Lfs*53 | Frame Shift Del (DEL) | VAF 13/114 reads (11%) | called by mutect2, pindel, varscan2
- BCL11A | c.691del p.L231Cfs*15 (on ENST00000335712 / NM_001365609.1; = p.L265Cfs*15 on NM_018014.4) | Frame Shift Del (DEL) | VAF 9/68 reads (13%) | called by mutect2, pindel, varscan2
- BRWD1 | c.3423_3454del p.D1143Sfs*3 | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, pindel
- CASP8 | c.489_490del p.A165Pfs*14 (on ENST00000432109 / NM_033355.3; = p.A197Pfs*14 on NM_001228.4) | Frame Shift Del (DEL) | VAF 13/126 reads (10%) | called by mutect2, pindel, varscan2
- CBARP | c.1117del p.Q373Rfs*34 (on ENST00000382477; = p.Q353Rfs*37 on NM_152769.3) | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by mutect2, pindel, varscan2
- CCAR1 | c.541del p.Q181Kfs*2 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- CDH15 | c.2095del p.Q699Sfs*51 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by mutect2, pindel, varscan2
- CENPF | c.447dup p.T150Yfs*11 | Frame Shift Ins (INS) | VAF 8/66 reads (12%) | called by mutect2, pindel
- CFAP74 | c.4347C>A p.S1449R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CNTN3 | c.136del p.I46* | Frame Shift Del (DEL) | VAF 12/79 reads (15%) | called by mutect2, pindel, varscan2
- CPN2 | c.1397del p.G466Afs*37 | Frame Shift Del (DEL) | VAF 9/88 reads (10%) | called by mutect2, pindel, varscan2
- CYLD | c.2165del p.N722Mfs*13 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by mutect2, pindel, varscan2
- ENDOD1 | c.844del p.I282Sfs*64 | Frame Shift Del (DEL) | VAF 8/90 reads (9%) | called by mutect2, pindel
- EPS8L2 | c.24C>G p.S8R | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); called by muse, mutect2
- FAAH | c.694del p.L232Wfs*3 | Frame Shift Del (DEL) | VAF 24/96 reads (25%) | called by mutect2, varscan2
- FAF2 | c.1281_1300del p.Q427Hfs*11 | Frame Shift Del (DEL) | VAF 12/135 reads (9%) | called by mutect2, pindel
- FILIP1 | c.508_513del p.L170_L171del | In Frame Del (DEL) | VAF 10/77 reads (13%) | called by mutect2, pindel, varscan2
- FNDC3A | c.567_572dup p.L190_K191dup (on ENST00000492622 / NM_001079673.2; = p.L134_K135dup on NM_014923.5) | In Frame Ins (INS) | VAF 10/74 reads (14%) | called by mutect2, varscan2
- H1-0 | c.477del p.K159Nfs*21 | Frame Shift Del (DEL) | VAF 10/61 reads (16%) | called by mutect2, pindel, varscan2
- INPP5A | c.347del p.N116Tfs*25 | Frame Shift Del (DEL) | VAF 15/104 reads (14%) | called by mutect2, pindel, varscan2
- IQCJ-SCHIP1 | c.1310_1325del p.Q437Lfs*18 (on ENST00000485419 / NM_001197113.1; = p.Q361Lfs*18 on NM_014575.3) | Frame Shift Del (DEL) | VAF 20/169 reads (12%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, varscan2
- KCNMA1 | c.2076del p.K692Nfs*15 (on ENST00000286628 / NM_001161352.2; = p.K692Nfs*36 on NM_002247.4) | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | called by mutect2, varscan2
- LYSMD3 | c.540_541dup p.N181Rfs*6 | Frame Shift Ins (INS) | VAF 14/83 reads (17%) | called by mutect2, varscan2
- MAPRE3 | c.543del p.C182Afs*31 | Frame Shift Del (DEL) | VAF 10/68 reads (15%) | called by mutect2, varscan2
- MFSD10 | c.452dup p.I152Hfs*15 | Frame Shift Ins (INS) | VAF 11/68 reads (16%) | called by mutect2, pindel, varscan2
- NINL | c.628del p.V210Wfs*7 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | called by mutect2, pindel, varscan2
- NLGN4Y | c.2173_2188del p.Q725Cfs*5 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | called by mutect2, pindel, varscan2
- NLRP4 | c.1496del p.L499Wfs*5 | Frame Shift Del (DEL) | VAF 16/98 reads (16%) | called by mutect2, pindel, varscan2
- NR2C2 | c.528dup p.C177Mfs*14 (on ENST00000393102; = p.C196Mfs*14 on NM_003298.5) | Frame Shift Ins (INS) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- NUTM2A | c.473_489del p.G158Afs*107 | Frame Shift Del (DEL) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- OAS2 | c.968del p.N323Tfs*41 | Frame Shift Del (DEL) | VAF 16/107 reads (15%) | called by mutect2, pindel, varscan2
- OGDH | c.2847dup p.N950Qfs*3 | Frame Shift Ins (INS) | VAF 15/136 reads (11%) | called by mutect2, pindel, varscan2
- PCDHA4 | c.421_445del p.S141Tfs*6 | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | called by mutect2, pindel, varscan2
- PCED1B | c.157del p.E53Sfs*2 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel, varscan2
- PLAGL2 | c.30del p.W11Gfs*15 | Frame Shift Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- PLEKHA6 | c.1154del p.P385Rfs*115 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- PLEKHO2 | c.938del p.P313Hfs*9 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel, varscan2
- POLR2B | c.2463del p.G822Dfs*19 | Frame Shift Del (DEL) | VAF 10/43 reads (23%) | called by mutect2, pindel, varscan2
- PPOX | c.363del p.F122Sfs*10 | Frame Shift Del (DEL) | VAF 15/127 reads (12%) | called by mutect2, pindel, varscan2
- PPP2R5B | c.1077del p.F359Lfs*29 | Frame Shift Del (DEL) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- PRG4 | c.3090dup p.P1031Tfs*12 | Frame Shift Ins (INS) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- PSMD14 | c.339del p.H113Qfs*39 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel, varscan2
- R3HDM2 | c.1804_1833+7del p.X602_splice | Splice Site (DEL) | VAF 9/83 reads (11%) | called by mutect2, pindel
- SEMA3E | c.941del p.L314Cfs*11 | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- SH3TC2 | c.2688_2695delinsCA p.R896_L899delinsSI | In Frame Del (DEL) | VAF 30/158 reads (19%) | called by pindel, varscan2*
- SLC17A6 | c.569_573+21del p.X190_splice | Splice Site (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel
- SLC25A13 | c.948_957del p.S317Qfs*33 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | called by mutect2, pindel
- SLC33A1 | c.1149-16_1149-3del | Splice Region (DEL) | VAF 12/69 reads (17%) | called by mutect2, pindel
- SNX6 | c.1096dup p.I366Nfs*3 (on ENST00000652385; = p.I238Nfs*3 on NM_021249.5) | Frame Shift Ins (INS) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- SP5 | c.310_328del p.G106Pfs*202 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, pindel
- SPDYC | c.654dup p.C219Lfs*13 | Frame Shift Ins (INS) | VAF 13/64 reads (20%) | called by mutect2, pindel, varscan2
- TAS2R16 | c.73_91del p.S25Cfs*12 | Frame Shift Del (DEL) | VAF 10/74 reads (14%) | called by mutect2, varscan2
- TAS2R8 | c.36_42del p.I13Efs*5 | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | called by mutect2, pindel
- TBL2 | c.1023del p.N342Tfs*75 | Frame Shift Del (DEL) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- TDO2 | c.348_357del p.H116Qfs*2 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | called by mutect2, pindel, varscan2
- TECPR1 | c.1692_1693del p.M565Afs*101 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by pindel, varscan2
- TFPI | c.307del p.M103Cfs*11 | Frame Shift Del (DEL) | VAF 12/71 reads (17%) | called by mutect2, pindel, varscan2
- TM9SF4 | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- TMTC3 | c.539del p.L180* | Frame Shift Del (DEL) | VAF 24/127 reads (19%) | called by mutect2, pindel, varscan2
- TRBV20-1 | c.289A>G p.S97G | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- TTC14 | c.2061dup p.Y688Ifs*8 | Frame Shift Ins (INS) | VAF 13/72 reads (18%) | called by mutect2, pindel, varscan2
- TTN | c.5132_5142del p.S1711* (on ENST00000591111; = p.S1665* on NM_003319.4) | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel
- UBQLNL | c.1221_1245del p.R407Sfs*15 | Frame Shift Del (DEL) | VAF 14/94 reads (15%) | called by mutect2, pindel
- USB1 | c.720_748del p.E241Sfs*68 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- VWA3A | c.1601_1603dup p.R534dup | In Frame Ins (INS) | VAF 12/87 reads (14%) | called by mutect2, pindel, varscan2
- WBP2NL | c.764del p.P255Hfs*63 | Frame Shift Del (DEL) | VAF 62/284 reads (22%) | called by mutect2, varscan2
- ZNF692 | c.582_596del p.E194_N198del | In Frame Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- ABCC10 | c.3780G>A p.P1260= (on ENST00000372530 / NM_001198934.2; = p.P1232= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/279 reads (13%) | catalogued as rs747994509, COSV55086861; called by muse, mutect2, varscan2
- ADGRE2 | c.507C>T p.S169= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs748645336, COSV59693078, COSV59694836; called by muse, mutect2, varscan2
- AKAP11 | c.1293G>A p.P431= | Silent (SNP) | VAF 40/170 reads (24%) | catalogued as rs139837011, COSV50296024; called by muse, mutect2, varscan2
- ATP10A | c.2439C>T p.I813= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as rs778064004, COSV63516405; called by muse, mutect2, varscan2
- BACE1 | c.1023C>T p.F341= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV57284564; called by muse, mutect2, varscan2
- C10orf90 | c.925C>T p.L309= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV52953697; called by muse, mutect2, varscan2
- C11orf24 | c.180T>G p.A60= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as rs756189233, COSV58505410; called by muse, mutect2, varscan2
- CARMIL3 | c.1479C>T p.F493= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as rs752362667, COSV57726043; called by muse, mutect2, varscan2
- CD27 | c.285C>T p.N95= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV56946600; called by muse, mutect2, varscan2
- CD300LF | c.192C>A p.I64= | Silent (SNP) | VAF 59/240 reads (25%) | catalogued as COSV56896747; called by muse, mutect2, varscan2
- CDCP2 | c.444C>G p.V148= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100313719, COSV61283529; called by muse, mutect2, varscan2
- CEP63 | c.1152T>C p.H384= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV59675829; called by muse, mutect2, varscan2
- CEP89 | c.864T>C p.A288= | Silent (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- CLCN7 | c.1977C>T p.N659= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs182360535; called by mutect2, varscan2
- CLDN19 | c.363C>T p.A121= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs771578996, COSV56417773; called by mutect2, varscan2
- CSMD3 | c.8682T>C p.N2894= (on ENST00000297405 / NM_001363185.1; = p.N2725= on NM_052900.3) | Silent (SNP) | VAF 14/114 reads (12%) | catalogued as rs747631575, COSV52159851; called by muse, mutect2, varscan2
- DCLRE1C | c.1419G>A p.L473= (on ENST00000378278 / NM_001350965.2; = p.L358= on NM_022487.4) | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as rs894826033, COSV57953648; called by muse, mutect2
- DGKH | c.3225G>A p.S1075= | Silent (SNP) | VAF 38/193 reads (20%) | catalogued as rs1356028406, COSV54930937; called by muse, mutect2, varscan2
- DIP2B | c.3180C>T p.I1060= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs747998083, COSV56582858; called by muse, mutect2, varscan2
- DISP1 | c.2571A>G p.K857= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV52657830; called by muse, mutect2, varscan2
- DMBT1 | c.6798C>T p.S2266= (on ENST00000338354 / NM_001377530.1; = p.S1509= on NM_004406.3) | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV57541464; called by muse, mutect2, varscan2
- DSG4 | c.1230A>T p.T410= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV57390806; called by muse, mutect2, varscan2
- EDC4 | c.3981T>C p.S1327= | Silent (SNP) | VAF 34/166 reads (20%) | catalogued as COSV59302526; called by muse, mutect2, varscan2
- EFHC1 | c.937C>T p.L313= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV64136139; called by muse, mutect2, varscan2
- EGR1 | c.549C>T p.S183= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as rs202122132, COSV53518960; called by muse, mutect2, varscan2
- EIF3A | c.2391G>A p.Q797= | Silent (SNP) | VAF 36/231 reads (16%) | catalogued as COSV64961145; called by muse, mutect2, varscan2
- EPB41L4B | c.2139C>T p.S713= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as rs754740283, COSV63124179; called by muse, varscan2
- EXO1 | c.225C>T p.L75= | Silent (SNP) | VAF 24/178 reads (13%) | catalogued as rs141548668; called by muse, mutect2, varscan2
- EXOSC5 | c.651G>A p.S217= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs540292584, COSV55370937; called by muse, mutect2
- FAH | c.111C>T p.G37= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs753555433, COSV55721149; called by muse, mutect2, varscan2
- FAM83D | c.1182G>A p.E394= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV54157225; called by muse, mutect2
- FAM98C | c.441A>C p.V147= | Silent (SNP) | VAF 46/154 reads (30%) | catalogued as COSV53038657; called by muse, mutect2, varscan2
- FLNA | c.3972C>T p.Y1324= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs782259468, CM157472, COSV61041704; called by muse, mutect2, varscan2
- FRG2C | c.153C>T p.S51= | Silent (SNP) | VAF 16/266 reads (6%) | called by muse, mutect2
- FZD1 | c.1836C>T p.I612= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV55310077; called by muse, mutect2, varscan2
- GABRA4 | c.1107A>G p.R369= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV51926359; called by muse, mutect2, varscan2
- GIMAP4 | c.117C>T p.T39= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as rs367979869; called by muse, mutect2, varscan2
- GIMAP6 | c.678C>T p.N226= | Silent (SNP) | VAF 35/216 reads (16%) | catalogued as rs771076874, COSV61033181, COSV61033285; called by muse, mutect2, varscan2
- GJC2 | c.756C>T p.H252= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV64512706; called by muse, mutect2
- GLT6D1 | c.282G>A p.P94= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as rs765609739, COSV65627602; called by muse, mutect2, varscan2
- GPR26 | c.594G>T p.V198= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV99500911; called by muse, varscan2
- GRM8 | c.666T>G p.A222= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV58820324; called by muse, mutect2, varscan2
- GSPT2 | c.996T>C p.H332= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV61214144; called by muse, mutect2, varscan2
- H2BU1 | c.303G>A p.L101= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV64209693; called by muse, mutect2, varscan2
- HEATR5A | c.1026G>A p.P342= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as rs774717077, COSV66340072; called by muse, mutect2, varscan2
- HOXC13 | c.576G>A p.S192= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV54498569; called by muse, mutect2, varscan2
- HTR4 | c.744T>C p.T248= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV58793682; called by muse, mutect2, varscan2
- IDE | c.438T>C p.H146= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV56422859; called by muse, mutect2, varscan2
- IGLV3-16 | c.294A>G p.A98= | Silent (SNP) | VAF 5/41 reads (12%) | called by mutect2, varscan2
- KIAA1549L | c.426C>G p.A142= (on ENST00000321505; = p.A439= on NM_012194.3) | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV55772474; called by muse, mutect2, varscan2
- KRT4 | c.843C>A p.S281= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV53406917; called by muse, mutect2, varscan2
- KRT73 | c.1312C>T p.L438= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV59838889; called by muse, mutect2, varscan2
- LAMA1 | c.720C>T p.T240= | Silent (SNP) | VAF 9/79 reads (11%) | catalogued as COSV67535757; called by muse, varscan2
- LRRC2 | c.222G>A p.R74= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as COSV56125822; called by muse, mutect2, varscan2
- LRRC27 | c.1563A>G p.G521= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV63996817; called by muse, mutect2, varscan2
- LRRC66 | c.1146A>C p.S382= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV58631943; called by muse, mutect2, varscan2
- LRRTM4 | c.465C>T p.G155= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV69139808; called by muse, mutect2, varscan2
- MAGEC1 | c.1458C>A p.S486= | Silent (SNP) | VAF 54/160 reads (34%) | catalogued as COSV53571573; called by muse, mutect2, varscan2
- MAP2 | c.3033C>T p.S1011= | Silent (SNP) | VAF 17/85 reads (20%) | catalogued as COSV52288517; called by muse, mutect2, varscan2
- MAP3K19 | c.405G>A p.K135= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV100208571; called by muse, mutect2, varscan2
- MAP3K3 | c.1722C>T p.A574= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as rs754221571, COSV51991668; called by muse, mutect2, varscan2
- MAP7D3 | c.1296G>T p.G432= | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as rs376124820, COSV60170711; called by muse, mutect2, varscan2
- MAPKBP1 | c.673C>T p.L225= | Silent (SNP) | VAF 5/57 reads (9%) | catalogued as rs1421502034, COSV52960503; called by muse, mutect2
- MAST3 | c.2238G>A p.L746= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV53219793; called by muse, varscan2
- MBD5 | c.2553G>A p.A851= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as rs559879867, COSV68696704; called by muse, varscan2
- MN1 | c.3123G>A p.V1041= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV56557819; called by muse, mutect2, varscan2
- MOV10L1 | c.237A>G p.A79= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs779143851, COSV53170195; called by muse, mutect2, varscan2
- MUC16 | c.10545T>C p.H3515= | Silent (SNP) | VAF 20/126 reads (16%) | catalogued as COSV67461388, COSV67477473; called by muse, mutect2, varscan2
- MUC16 | c.8937T>G p.T2979= | Silent (SNP) | VAF 21/119 reads (18%) | catalogued as COSV67461394; called by muse, mutect2, varscan2
- MUC16 | c.6063T>C p.S2021= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV67461401; called by muse, mutect2, varscan2
- MVP | c.558C>T p.D186= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs772883962, COSV62421907; called by muse, mutect2, varscan2
- MYBL2 | c.1888T>C p.L630= | Silent (SNP) | VAF 37/310 reads (12%) | catalogued as COSV53829256; called by muse, mutect2, varscan2
- MYO1F | c.1263C>T p.A421= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs767449105, COSV57794260; called by muse, mutect2, varscan2
- NARS2 | c.48C>T p.S16= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs771259800, COSV55251202; called by muse, mutect2, varscan2
- NDC80 | c.1095C>T p.D365= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV55247795; called by muse, mutect2, varscan2
- NECAB2 | c.822C>T p.R274= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs778432334, COSV59420291; called by muse, mutect2, varscan2
- NEDD9 | c.1617C>T p.P539= | Silent (SNP) | VAF 25/142 reads (18%) | catalogued as rs146690144; called by muse, mutect2, varscan2
- NEFM | c.1332C>G p.P444= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV55331714; called by muse, mutect2, varscan2
- NEURL3 | c.435G>A p.L145= | Silent (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- NHLH2 | c.369C>A p.I123= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV57201974; called by mutect2, varscan2
- NKX2-5 | c.504C>T p.R168= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as COSV61298845; called by muse, mutect2
- NLGN1 | c.1530C>A p.P510= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV64330879; called by muse, mutect2, varscan2
- NPAS1 | c.114C>A p.S38= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV71383965; called by muse, mutect2, varscan2
- NPHS1 | c.2760T>C p.C920= | Silent (SNP) | VAF 11/48 reads (23%) | catalogued as COSV62287463; called by muse, mutect2, varscan2
- NSF | c.1977C>T p.N659= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs745772478, COSV56574418; called by muse, mutect2, varscan2
- NTRK3 | c.693C>T p.C231= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs1462618295, COSV58107131, COSV58119028; called by muse, mutect2
- OR10T2 | c.759C>T p.G253= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV57780982; called by muse, mutect2, varscan2
- OR2T2 | c.921G>T p.G307= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV100737666, COSV61619043; called by muse, varscan2
- OR6C6 | c.474G>A p.L158= | Silent (SNP) | VAF 14/89 reads (16%) | catalogued as COSV100626500, COSV64455712; called by muse, mutect2, varscan2
- OR8H3 | c.699A>G p.G233= | Silent (SNP) | VAF 24/123 reads (20%) | catalogued as COSV57908616; called by mutect2, varscan2
- P2RX6 | c.579C>A p.A193= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV60382210; called by muse, mutect2, varscan2
- PAPLN | c.2877C>T p.F959= (on ENST00000554301; = p.F932= on NM_173462.4) | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as rs369723468; called by muse, mutect2, varscan2
- PAQR7 | c.966G>A p.T322= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs751929346, COSV65351617; called by muse, mutect2, varscan2
- PASD1 | c.705T>A p.A235= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV64854932; called by muse, mutect2, varscan2
- PCDHGA8 | c.546G>T p.V182= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as COSV53933245; called by muse, mutect2, varscan2
- PCDHGB7 | c.1380C>T p.H460= | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as rs374093302; called by muse, mutect2, varscan2
- PCLO | c.10341G>A p.T3447= | Silent (SNP) | VAF 16/99 reads (16%) | catalogued as rs566457960, COSV61615170, COSV61629759; called by muse, mutect2, varscan2
- PHKG1 | c.891G>A p.R297= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV51916187; called by muse, mutect2, varscan2
- PHPT1 | c.81C>T p.V27= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV56032621; called by muse, mutect2, varscan2
- PKHD1 | c.3015C>T p.A1005= | Silent (SNP) | VAF 21/121 reads (17%) | catalogued as COSV61871765, COSV61883821; called by muse, mutect2, varscan2
- PKP2 | c.714G>A p.P238= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs727503372, COSV50729362; ClinVar: likely benign; called by mutect2, varscan2
- PLCH1 | c.1122G>A p.E374= (on ENST00000340059 / NM_001130960.2; = p.E386= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV58194167; called by muse, mutect2, varscan2
- PRKAR2B | c.666C>T p.G222= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs146903153; called by muse, mutect2, varscan2
- PRODH2 | c.57T>C p.I19= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV56559395; called by muse, mutect2, varscan2
- PSG8 | c.1020A>G p.S340= | Silent (SNP) | VAF 36/186 reads (19%) | catalogued as rs1353121755, COSV100126207; called by muse, mutect2, varscan2
- PTPN11 | c.1467C>T p.D489= | Silent (SNP) | VAF 22/115 reads (19%) | catalogued as rs539373294, COSV61008275; ClinVar: likely benign; called by muse, mutect2, varscan2
- PWWP2B | c.1341G>A p.S447= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as rs370369167; called by muse, mutect2, varscan2
- RAB6C | c.718T>C p.L240= | Silent (SNP) | VAF 14/108 reads (13%) | catalogued as COSV69339436; called by muse, mutect2, varscan2
- RHEBL1 | c.87C>T p.G29= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV56504239; called by muse, mutect2, varscan2
- RIF1 | c.1428T>C p.N476= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV54615947; called by muse, mutect2, varscan2
56 further variants in this file (0 protein-altering or splice-affecting, 44 silent, 12 other) are not listed here.
